Somatic mutation profile of tumor specimen 0D9HZA from CCDI case PBBIUN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 13.1 years (4,802 days).
Specimen 0D9HZA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8acff1c-271a-4b96-8a95-7b8f89611359.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9HZ2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03ca2bea-844f-4f33-a941-85d6595b501e

The open-access MAF lists 22 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Intron 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 265/689 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 298/356 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EPHA5 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 276/640 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.067); catalogued as rs749830045, COSV56645016; called by muse, mutect2, varscan2
- INSL4 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 210/496 reads (42%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs370426005, COSV53329013; called by muse, mutect2, varscan2
- SLC25A2 | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 225/414 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.384); catalogued as rs868972054, COSV53403118; called by muse, mutect2, varscan2
- TTN | c.80873G>A p.R26958H (on ENST00000591111; = p.R19534H on NM_003319.4) | Missense Mutation (SNP) | VAF 194/418 reads (46%) | PolyPhen probably damaging (0.998); catalogued as rs558543425; called by muse, mutect2, varscan2
- ERCC6 | c.336G>C p.Q112H | Missense Mutation (SNP) | VAF 104/239 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GCNA | c.1878G>T p.E626D | Missense Mutation (SNP) | VAF 175/192 reads (91%) | SIFT tolerated (0.05); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- HSPA6 | c.930C>A p.D310E | Missense Mutation (SNP) | VAF 101/668 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- IFNA21 | c.266A>G p.N89S | Missense Mutation (SNP) | VAF 93/504 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- LCN15 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 18/426 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by muse, mutect2
- MGAT5 | c.1859T>C p.I620T | Missense Mutation (SNP) | VAF 302/782 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- PTPRM | c.895T>C p.W299R | Missense Mutation (SNP) | VAF 40/440 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- RABGEF1 | c.454T>A p.S152T (on ENST00000439720 / NM_001287061.2; = p.S139T on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 308/677 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ALLC | c.450C>T p.H150= | Silent (SNP) | VAF 293/796 reads (37%) | called by muse, mutect2, varscan2
- MMP7 | c.543G>A p.A181= | Silent (SNP) | VAF 55/527 reads (10%) | catalogued as rs149122882; called by muse, mutect2, varscan2
- SIRT7 | c.1200G>A p.T400= | Silent (SNP) | VAF 134/298 reads (45%) | catalogued as rs374568755; called by muse, mutect2, varscan2
- TTN | c.33651A>T p.A11217= (on ENST00000591111; = p.A10290= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 92/974 reads (9%) | catalogued as rs975292109; called by muse, mutect2
- ZNF695 | c.51G>A p.E17= | Silent (SNP) | VAF 357/692 reads (52%) | catalogued as rs1314036783; called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 7/112 reads (6%) | called by muse, mutect2
- IK | c.1355+78C>A | Intron (SNP) | VAF 4/34 reads (12%) | called by mutect2, varscan2
- RACK1 | c.281+17T>G | Intron (SNP) | VAF 137/436 reads (31%) | called by muse, mutect2, varscan2
